Somatic mutation profile of tumor specimen TARGET-30-PAMVRA-01A (aliquot TARGET-30-PAMVRA-01A-01W) from TARGET case TARGET-30-PAMVRA, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.3 years (1,554 days).
Specimen TARGET-30-PAMVRA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d52f5d94-e70b-46ef-93d5-20282f468dc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMVRA-10A (Blood Derived Normal), aliquot TARGET-30-PAMVRA-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61819825-957f-4078-9657-dd69844e080d

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRPV3 | c.259dup p.Q87Pfs*6 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs911130511; called by pindel, varscan2
